Somatic mutation profile of tumor specimen TARGET-10-PARXVS-09A (aliquot TARGET-10-PARXVS-09A-01D) from TARGET case TARGET-10-PARXVS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.8 years (4,292 days).
Specimen TARGET-10-PARXVS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 208f2310-0595-4649-9285-034252111d0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARXVS-10A (Blood Derived Normal), aliquot TARGET-10-PARXVS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25483391-04ef-45f1-b057-85ebb58788dd

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Nonsense Mutation 3, Silent 3, In Frame Del 2, In Frame Ins 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 33/35 reads (94%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 11/105 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF10 | c.1038G>T p.M346I (on ENST00000398564; = p.M321I on NM_014629.4) | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV50680116; called by muse, mutect2, varscan2
- BLCAP | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1470854314, COSV50351734; called by mutect2, varscan2
- CFAP43 | c.3982G>T p.V1328F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV63852657; called by muse, mutect2
- DYTN | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV71753070; called by muse, mutect2, varscan2
- EPHA2 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1028392500, COSV64454787; called by muse, mutect2
- FAT1 | c.5524A>G p.I1842V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs370764338; called by muse, varscan2
- HNF4A | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV57389322; called by muse, mutect2, varscan2
- NCOR1 | c.4346C>T p.T1449M | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs779429826, COSV51997286; called by muse, mutect2, varscan2
- RAVER2 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV53811079; called by muse, mutect2, varscan2
- SYNE1 | c.4163G>A p.R1388Q (on ENST00000367255 / NM_182961.4; = p.R1395Q on NM_033071.3) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770990182, COSV54935437; called by muse, mutect2, varscan2
- TIGD2 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57647219; called by muse, mutect2
- USP7 | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 70/152 reads (46%) | catalogued as COSV61217629; called by muse, mutect2, varscan2
- ZNF554 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV57887077; called by muse, mutect2, varscan2
- AKT3 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BTRC | c.1660C>A p.H554N (on ENST00000370187 / NM_033637.4; = p.H518N on NM_003939.5) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ECT2 | c.2519C>A p.A840E (on ENST00000392692 / NM_001349098.2; = p.A809E on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- MATR3 | c.708dup p.G237Wfs*2 | Frame Shift Ins (INS) | VAF 32/158 reads (20%) | called by mutect2, varscan2
- MBNL1 | c.96_97insCCG p.T32_E33insP | In Frame Ins (INS) | VAF 32/100 reads (32%) | called by mutect2, pindel, varscan2
- MED19 | c.639G>T p.R213S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- NOTCH1 | c.5026_5028del p.V1676del | In Frame Del (DEL) | VAF 23/125 reads (18%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.4735_4737del p.L1579del | In Frame Del (DEL) | VAF 6/30 reads (20%) | called by pindel, varscan2
- DNAH10 | c.6642C>T p.Y2214= (on ENST00000409039; = p.Y2153= on NM_207437.3) | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as rs753490414, COSV68995135; called by muse, mutect2, varscan2
- HUS1 | c.156G>T p.V52= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- KIFC3 | c.45T>A p.A15= | Silent (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- ATP6AP2 | c.301-35C>A | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
